Somatic mutation profile of tumor specimen C3L-01158-01 (aliquot CPT0171630022) from CPTAC case C3L-01158, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.1 years (25,247 days).
Specimen C3L-01158-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2798d85-72af-4873-9e13-4e92f8b6cf0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01158-31 (Blood Derived Normal), aliquot CPT0171560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d9fbe77-88f4-4859-a5a5-11439bde45c3

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 8, Intron 2, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 109/636 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 410/904 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.3317C>T p.T1106M | Missense Mutation (SNP) | VAF 87/914 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs139677111; called by muse, mutect2
- ATP2B3 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 222/763 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141644369, COSV54848658; called by muse, mutect2, varscan2
- CBFA2T3 | c.949C>T p.R317W | Missense Mutation (SNP) | VAF 277/1311 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1432631709, COSV51924049; called by muse, mutect2, varscan2
- CLEC11A | c.422A>G p.Q141R | Missense Mutation (SNP) | VAF 229/1525 reads (15%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1163617798; called by muse, mutect2, varscan2
- COL9A1 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 151/571 reads (26%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.937); catalogued as rs761249181, COSV100295424; called by muse, mutect2, varscan2
- DNAH5 | c.11528C>T p.S3843L | Missense Mutation (SNP) | VAF 147/578 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs78346432, CM065132, COSV54202507; called by muse, mutect2, varscan2
- DPF3 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 170/869 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.915); catalogued as rs771502693, COSV63500981; called by muse, mutect2, varscan2
- EDA | c.1051G>A p.V351I | Missense Mutation (SNP) | VAF 157/1187 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs758752553; called by muse, mutect2, varscan2
- FAM47A | c.1555T>C p.S519P | Missense Mutation (SNP) | VAF 112/935 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs867589029, COSV60496026; called by muse, varscan2
- HPS4 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 119/885 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs758902895, COSV61102932; called by muse, mutect2, varscan2
- KCNB2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 50/1193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73048998, COSV73050348; called by muse, mutect2
- NME1 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 116/581 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs375550760; called by muse, mutect2, varscan2
- OTOF | c.3428G>A p.R1143Q (on ENST00000272371 / NM_194248.3; = p.R396Q on NM_004802.4) | Missense Mutation (SNP) | VAF 82/960 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1330253297; called by muse, mutect2
- PCDH12 | c.1915C>T p.R639C | Missense Mutation (SNP) | VAF 257/1086 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.594); catalogued as rs370147049; called by muse, mutect2, varscan2
- PDZRN4 | c.2830G>A p.E944K (on ENST00000402685 / NM_001164595.2; = p.E686K on NM_013377.4) | Missense Mutation (SNP) | VAF 206/1025 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1350158553, COSV54192586; called by muse, mutect2, varscan2
- PES1 | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 240/967 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.196); catalogued as rs142150429; called by muse, mutect2, varscan2
- SFTPA1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 25/696 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV64867869; called by muse, mutect2
- SLC12A3 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 154/726 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs758304056, COSV52638027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC2A11 | c.205C>T p.L69F (on ENST00000345044 / NM_001024938.4; = p.L76F on NM_030807.5) | Missense Mutation (SNP) | VAF 218/985 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs1200541777; called by muse, mutect2, varscan2
- SLC35F3 | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 227/1025 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.938); catalogued as rs111543981, COSV64033094; called by muse, mutect2, varscan2
- STRN3 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 74/764 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs372983140; called by muse, mutect2
- TTLL12 | c.1063C>G p.L355V | Missense Mutation (SNP) | VAF 185/847 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as COSV53356917; called by muse, mutect2, varscan2
- WNT2 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 204/957 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs753385406; called by muse, mutect2, varscan2
- ACBD4 | c.80_87dup p.G30Pfs*53 | Frame Shift Ins (INS) | VAF 114/602 reads (19%) | called by mutect2, varscan2
- ADGRF3 | c.2875G>A p.G959R (on ENST00000311519 / NM_001145168.1; = p.G760R on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 213/986 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- AIFM3 | c.1577-8G>T | Splice Region (SNP) | VAF 64/824 reads (8%) | called by muse, mutect2
- EMC10 | c.239A>T p.D80V | Missense Mutation (SNP) | VAF 116/1266 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2
- FLNB | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 90/718 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRT82 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 147/1374 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- PGM5 | c.1525C>A p.L509I | Missense Mutation (SNP) | VAF 98/968 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2
- RIPOR1 | c.2306A>T p.H769L (on ENST00000379312 / NM_001193522.2; = p.H765L on NM_024519.4) | Missense Mutation (SNP) | VAF 286/1444 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2
- SCN2A | c.2115G>A p.M705I | Missense Mutation (SNP) | VAF 136/619 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TBC1D22B | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 58/524 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- XKR3 | c.292G>T p.A98S | Missense Mutation (SNP) | VAF 52/447 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZBTB10 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 316/1356 reads (23%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 153/625 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF354A | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 141/680 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CDH11 | c.426G>A p.P142= | Silent (SNP) | VAF 237/1005 reads (24%) | catalogued as rs758854974, COSV51776352; called by muse, mutect2, varscan2
- CELSR3 | c.7227T>A p.I2409= | Silent (SNP) | VAF 192/913 reads (21%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1809G>A p.L603= | Silent (SNP) | VAF 291/1996 reads (15%) | called by muse, varscan2
- POLD1 | c.2874G>C p.L958= | Silent (SNP) | VAF 256/1600 reads (16%) | called by muse, mutect2, varscan2
- RRM2 | c.1023C>T p.F341= | Silent (SNP) | VAF 98/476 reads (21%) | called by muse, mutect2, varscan2
- SFPQ | c.1149C>T p.S383= | Silent (SNP) | VAF 101/736 reads (14%) | catalogued as rs1031911553, COSV100599458; called by muse, mutect2, varscan2
- SPRY1 | c.225A>G p.E75= | Silent (SNP) | VAF 101/801 reads (13%) | called by muse, mutect2, varscan2
- TBX19 | c.378G>A p.P126= | Silent (SNP) | VAF 110/981 reads (11%) | called by muse, mutect2, varscan2
- BBS4 | c.1106+46A>G | Intron (SNP) | VAF 22/229 reads (10%) | called by muse, mutect2, varscan2
- COPS7B | c.636+2201G>A | Intron (SNP) | VAF 115/649 reads (18%) | catalogued as rs758206981, COSV100602260; called by muse, mutect2, varscan2
- SPATA31C2 | n.3331G>A | RNA (SNP) | VAF 22/382 reads (6%) | catalogued as rs780784638; called by muse, mutect2
